TCGA case TCGA-HT-7620 — Brain Lower Grade Glioma (TCGA-LGG)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Case Western - St Joes. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0d61bdbd-24b1-4885-a099-9e42ca7eedcd

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 40 years; Vital status: Alive.

Diagnoses (2)
1. Oligodendroglioma, anaplastic (the primary disease): ICD-O-3 morphology code: 9451/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Nervous system, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 40.1 years (14,659 days); Year of diagnosis: 2007; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 434 days (1.2 years); First symptom longest duration: 0-30 Days; First symptom prior to diagnosis: Headaches; Sites of involvement: Brain, Frontal lobe; Supratentorial localization: White Matter.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 40 days; Days to treatment end: 70 days; Treatment dose: 60 cGy; Course number: 1; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 126 days; Number of cycles: 1; Prescribed dose: 150; Prescribed dose units: mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 195 days; Days to treatment end: 199 days; Number of cycles: 1; Treatment dose: 1,250 mg; Prescribed dose: 250; Prescribed dose units: mg/day; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Bevacizumab + Irinotecan; Initial disease status: Progressive Disease; Days to treatment start: 285 days.
   Treatment given: Treatment type: Antiseizure Treatment; Timepoint category: Preoperative.
   Treatment given: Treatment type: Steroid Therapy; Timepoint category: Preoperative.
   Recorded as not given: Radiation Therapy, NOS to Head, Face or Neck, NOS, prior to diagnosis.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 40.9 years (14,939 days); Days to diagnosis: 280 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Recorded as not given: Radiation Therapy, NOS; Surgery, NOS to Locoregional Site.

Follow-up (2 entries)
- Day 280 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 434 days (1.2 years); Disease response: Tumor Free.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: Allergies; Risk factors: Hay Fever.
- Timepoint category: Prior to Diagnosis; Risk factors: Headache / Motor / Movement Change / Sensory Changes / Vision Changes.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-HT-7620-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 3.7; Intermediate dimension: 1.1; Shortest dimension: 0.6.
  Slide TCGA-HT-7620-01A-01-BS1: Section location: Bottom; Percent tumor cells: 92; Percent tumor nuclei: 60; Percent normal cells: 8; Percent necrosis: 0; Percent stromal cells: 0.
  Slide TCGA-HT-7620-01A-01-TS1: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 60; Percent normal cells: 5; Percent necrosis: 0; Percent stromal cells: 0.
- Sample TCGA-HT-7620-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-HT-7620-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Central nervous system; Histologic diagnosis: Oligodendroglioma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; History ionizing radiation to head: No; Tumor status: Tumor free; Tumor site: Supratentorial, Frontal Lobe; History seizures: No; History headaches: Yes; Symp changes mental status: No; Symp changes visual: Yes; Symp changes sensory: Yes; Symp changes motor movement: Yes; First symptom longest duration: 0 - 30 Days; History asthma: No; History eczema: No; Histor hay fever: Yes; History dust mold allergy: No; Allergy food diagnosis indicator: No; Allergy animals insects diagnosis indicator: No; History neoadjuvant steroid treatment: Yes; History neoadjuvant medication: Yes; Family history brain tumor: No; Idh1 mutation test indicator: No; Inherited genetic syndrome indicator: No.
- Drug treatment 1: Regimen number: 1; Pharmaceutical therapy drug name: Temodar.
- Drug treatment 1, Route of administrations: Route of administration: PO.
- Drug treatment 2: Regimen number: 3; Therapy regimen: Progression.
- Drug treatment 3: Regimen number: 2; Pharmaceutical therapy drug name: Temodar.
- Drug treatment 4: Regimen number: 4; Pharmaceutical therapy drug name: Avastin; Therapy regimen: Progression.
- Follow-up form: Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: Yes; New tumor event surgery: No; New tumor event pharmaceutical treatment: Yes; New tumor event radiation treatment: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 434 days; disease-specific survival: no event (censored), 434 days; disease-free interval: event (new tumor event after initially disease-free), 280 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 280 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-HT-7620-01A-11D-2252-01): tumor purity 0.42, ploidy 1.94, whole-genome doublings 0.
